Surgical pathology report (de-identified scan), TCGA case TCGA-55-8506, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8506-01A (Primary Tumor).

[page 1 of 4]
DIAGNOSIS

A) LYMPH NODE, INFERIOR PULMONARY #9 (N2), BIOPSY: One lymph node negative for metastatic carcinoma (0/1)

B) LYMPH NODE, SUBCARINAL #7 (N2), BIOPSY: One lymph node negative for metastatic carcinoma

C) LYMPH NODES, HILAR RIGHT, #10R (N1), BIOPSY: Two lymph nodes negative for metastatic carcinoma (0/2)

D) LYMPH NODES, INTRALOBAR #11 (N1), BIOPSY: One lymph node negative for metastatic carcinoma (0/1)

E) LUNG AND CHEST WALL, RIGHT UPPER LOBE AND SOFT TISSUE, WITH RIBS 2,3,4 AND 5, EN BLOC RESECTION:

1. Adenocarcinoma, poorly-differentiated
2. Tumor involves the right upper lobe and extends through parietal and visceral pleura into chest wall soft tissue
3. Surgical margins are negative for tumor
4. Negative for lymphatic/vascular invasion by tumor
5. Ten peribronchial (N1) lymph nodes negative for metastasis (0/10)
6. Please see lung cancer staging parameters below

F) LYMPH NODE, SUBCARINAL #7 (N2), BIOPSY: One lymph node negative for metastatic carcinoma (0/1)

COMMENT

Immunohistochemical stains (see microscopic) are performed to confirm the tumor histology as adenocarcinoma. While this specimen does not meet the criteria for EGFR or ALK testing, such testing was performed on the patient's prior biopsy. Please see the final report staging parameters for those results.

Final TNM: pT3N0M0

Stage: IIB

MACROSCOPIC

SPECIMEN TYPE

Lobectomy, en bloc wall resection

TUMOR SITE

Right Lung-Upper Lobe

TUMOR SIZE

7 X 6 X 5 cm

[page 2 of 4]
TUMOR FOCALITY

Unifocal

MICROSCOPIC

HISTOLOGIC TYPE

Adenocarcinoma

HISTOLOGICAL GRADE

G3: (poorly differentiated) of G4

VISCERAL PLEURAL INVASION

Present

LYMPHATIC VASCULAR INVASION

Absent

TUMOR EXTENSION

Tumor extension(s) identified: Chest wall, Parietal pleura

MARGINS

Uninvolved by tumor

PATHOLOGIC STAGING

EXTENT OF INVASION

pT3. (Tumor greater than 7 cm in greatest dimension; or Tumor of any size that directly invades any of the following: parietal pleura (PL3) chest wall (including superior sulcus tumors), diaphragm, phrenic nerve, mediastinal pleura, parietal pericardium; or Tumor of any size in the main bronchus less than 2 cm distal to the carina but without involvement of the carina; or Tumor of any size associated with atelectasis or obstructive pneumonitis of the entire lung; or Tumors of any size with separate tumor nodule(s) in same lobe)

REGIONAL LYMPH NODES

pN0. (No regional lymph node metastasis)

Total nodes: 16

Total positive nodes: 0

N1 nodes: 13

N1 positive nodes: 0

N2 nodes: 3

N2 positive nodes: 0

DISTANT METASTASIS

pM0. (No distant metastasis)

PATHOLOGIC STAGE Summary

Final TNM: pT3N0M0

Stage: IIB

** The pathologic stage presumes no distant metastasis.

***LUNG ANCILLARY TESTING PROTOCOL ***

HISTOLOGIC TYPE

Adenocarcinoma

STAGE IV STATUS

No stage IV disease pathologically

TISSUE BLOCK AVAILABLE FOR ANCILLARY TESTING

E22-27

COMMENT

This patient's sample does not meet Lung Cancer Committee criteria* for reflex EGFR and ALK testing. No fresh tissue is available for ancillary testing. The block identified above will be stored in pathology for 10 years for possible future ancillary testing. Please call for any ancillary testing requests.

[page 3 of 4]
[REDACTED]

Adenocarcinoma or TTF-1 positive adenosquamous cell carcinoma.

PROGNOSTIC FACTORS (SITE SPECIFIC) AND ANCILLARY STUDIES

(Performed on case [REDACTED])

EGFR

Alteration detected L858R: increased responsiveness to TKIs

ALK GENE REARRANGEMENT

Not detected by FISH

Attending Pathologist [REDACTED]

[REDACTED]

CLINICAL INFORMATION

Lung cancer

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Lymph node #9, inferior pulmonary

Labeled "inferior pulmonary lymph node #9" consists of three yellow-tan focally anthracotic tissue fragments, ranging from 0.3-1 cm in greatest dimension. The specimen is submitted in toto in one cassette.

B) SOURCE: Lymph node, level 7

Labeled "level 7 lymph node" consists of four black anthracotic tissue fragments ranging from 0.6-1 cm in greatest dimension. The specimen is entirely submitted in two cassettes.

C) SOURCE: Lymph node, level 10R

Labeled "level 10R lymph node" consists of two tan-pink, 0.8-2 cm lymph nodes which are each sectioned and submitted in two separate cassettes (one node each cassette).

D) SOURCE: Lymph node, level 11

Labeled "level 11 lymph node" consists of a 1.1 cm pink-black anthracotic lymph node. The specimen is submitted in toto in one cassette.

[REDACTED]

E) SOURCE: Right upper lobe with en bloc chest wall resection; check bronchial margins

Labeled "right upper lobe with N block chest wall resection, check bronchial margins margin short - superior margin long - anterior margin" is a 402 gram, 12.5 x 10.5 x 7.5 cm composite resection of lung lobectomy (12 x 11.5 x 5 cm) in continuity with chest wall (10.5 x 7.3 x 2 cm) with four incorporated ribs (5.3, 10, 11, and 11.2 cm respectively in length).

The bronchial resection margin is received stapled, stapled margin trimmed and immediate subjacent tissue submitted on one block (two lumina) for frozen microscopy.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Bronchial margin benign" is rendered by [REDACTED]

The superior chest wall margin is inked blue, anterior chest wall and rib margins inked orange, inferior chest wall margin inked red, posterior chest wall and rib margins inked black, and the superficial chest wall margin inked green.

The lung is sectioned disclosing a solid firm yellow and gray-tan tumor mass with infiltrating irregular borders, measuring 7 x 6 x 5 cm in [REDACTED]

[REDACTED]

[page 4 of 4]
[REDACTED]

greatest dimension, 1.8 cm from the bronchial resection margin. The tumor extends through the visceral pleura invading the parietal pleura and soft tissues of the fibrously adhered adjacent chest wall, 1.1 cm from the posterior bone and soft tissue margin, 0.9 cm from the inferior soft tissue chest wall margin, 1.6 cm from the superior chest wall margin, 2.5 cm from the anterior chest wall margin. The tumor does not invade rib bone grossly.

The remaining cut surfaces of lung are congested, red-tan, soft, and without additional discrete lesions. There are multiple rubbery gray-black peribronchial lymph nodes up to 1.4 cm in greatest dimension. The pulmonary vasculature around the hilum is thin walled and lumina patent, without thrombi.

NOTE: Tissue is retained for additional possible ancillary studies.

Representative sections are submitted in 28 cassettes labeled:

- E1. Frozen section residue
- E2-E3. Anterior rib en face margins, sequentially from superior to inferior
- E4-E6. Posterior rib en face margins, sequentially from superior to inferior (cassettes E2-E6 are submitted following decalcification)
- E7. Vascular en face margin
- E8. One bisected peribronchial lymph node
- E9. One bisected peribronchial lymph node
- E10. Six peribronchial lymph nodes
- E11-E12. Superior chest wall en face soft tissue margin, sequentially from anterior to posterior
- E13. Anterior chest wall soft tissue en face margin
- E14-E17. Inferior chest wall en face soft tissue margin, sequentially from anterior to posterior
- E18-E21. Posterior en face chest wall soft tissue margin, sequentially from superior to inferior
- E22-E24. Tumor invading chest wall (no margin assessment)
- E25-E27. Tumor and adjacent lung
- E28. Normal lung
- [REDACTED]

[REDACTED]

F) SOURCE: Subcarinal lymph node biopsy
Labeled "subcarinal lymph node" is a 0.5 cm red-brown possible lymph node. The specimen is submitted in toto in one cassette.

This case is accessioned in [REDACTED]

[REDACTED]

MICROSCOPIC

A-F) The microscopic appearance substantiates the diagnosis. Immunohistochemical stains performed on block E23 reveal the tumor cells to be positive for TTF1, and mCEA (focal), and negative for CK5/6 and p63. The results support the diagnosis of adenocarcinoma.

[REDACTED]

Source: NCI Genomic Data Commons file 881953a0-fe59-48fd-ac87-4ccf948cc86a (TCGA-55-8506.448DE79C-D662-4783-A7C8-32A224EE5375.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).